Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A939, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A939-01A (Primary Tumor).

[page 1 of 6]
DEPARTMENT OF PATHOLOGY

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Service:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Visit #:	[REDACTED]	Collected:	
DOB:	[REDACTED]			Received:	
Gender:	M	Location:		Reported:	
Ordering MD:	[REDACTED]	Facility:			
Copy To:					

Specimen(s) Received

1. Lymph-Node: ST19 Splenic nodes
2. Lymph node: Stn 20 celiac nodes
3. Lymph node: Common hepatic nodes ST18
4. Lymph node: Common hepatic nodes ST18
5. Lymph node: Celiac nodes
6. Lymph node: Lymph node station 4L
7. Lymph node: Lymph node station 7
8. Soft Tissue: Thoracic esophagus proximal stomach
9. Soft Tissue: Proximal esophagus margin
10. Soft Tissue: Stomach margin
11. Lymph node: Lymph node STN7
12. Lymph node: Lymph node STN16
13. Lymph node: Lymph node STN17
14. Lymph node: Lymph node STN8
15. Soft Tissue: Final esophageal margin
16. Soft Tissue: Final gastric resection margin
17. Soft Tissue: Donuts

ICA-0-3

adenocarcinoma, NOS 8140/3

CRCF: Esophagus, distal third C15.5

Path: gastroesophageal junction C16.0

JW 5/20/14

Diagnosis

1. Lymph-Node: ST19 Splenic nodes:
- lymph node x1: negative for carcinoma
2. Lymph node: Stn 20 celiac nodes:
- lymph node x1: negative for carcinoma
3. Lymph node: Common hepatic nodes ST18:
- fibroadipose tissue and minute fragment of lymphoid tissue with diathermy effects, negative for carcinoma
4. Lymph node: Common hepatic nodes ST18
- lymph nodes x2: negative for carcinoma
5. Lymph node: Celiac nodes:
- lymph nodes x3: negative for carcinoma
6. Lymph node: Lymph node station 4L:
- lymph node x1: negative for carcinoma

[page 2 of 6]
7. Lymph node: Lymph node station 7:
- lymph nodes x4: negative for carcinoma

8. Thoracic esophagus and proximal stomach, resection:

- **adenocarcinoma of distal esophagus**, moderately to poorly differentiated, extending into GE junction and proximal stomach (cardia), invading submucosa – see synoptic data and comment
- metastatic adenocarcinoma in 1 perigastric lymph node (1/48, total lymph node count including specimens 1,2,4 to7 and 11 to 14)
- resection margins: negative for carcinoma

- intestinal metaplasia in area of GE junction/distal esophagus, consistent with Barrett's mucosa

9. Soft Tissue: Proximal esophagus margin
- negative for carcinoma

10. Soft Tissue: Stomach margin
- negative for carcinoma

11. Lymph node: Lymph node STN7:
- lymph nodes x3: negative for carcinoma

12. Lymph node: Lymph node STN16:
- lymph nodes x7: negative for carcinoma

13. Lymph node: Lymph node STN17:
- lymph nodes x12: negative for carcinoma

14. Lymph node: Lymph node STN8:
- lymph nodes x5: negative for carcinoma

15. Soft Tissue: Final esophageal margin:
- negative for carcinoma

16. Soft Tissue: Final gastric resection margin:
- negative for carcinoma

17. Soft Tissue: Donuts:
- portion of esophagus and stomach: negative for carcinoma.

Comment

8. The tumor involves both proximal stomach and distal esophagus, with the bulk of the tumor located in gastric cardia. The gastric portion of the tumor extends for about 5 cm from the GE junction and is mainly intramucosal. There is focal submucosal invasion in stomach as well as in esophagus. The junction of tumor with the esophagus shows some residual benign glands with goblet cells, in keeping with a segment of Barrett's esophagus. In view of the 5 cm distance of the gastric part of the tumor from the GE junction and the presence of intestinal metaplasia at the junction with the esophagus, the tumor is classified as an adenocarcinoma of distal esophagus. The tumor features areas of gland formation as well as sheets of cells with rare gland like lumina. There is prominent intra and peritumoral lymphocytic infiltrate. Immunohistochemical staining shows patchy positive labeling with CK7, CK20 and CDX2. The tumor is negative for chromogranin and synaptophysin.

There are a total of 48 lymph nodes identified including all specimens. There is one perigastric lymph node identified in the resection specimen (#8) with metastatic adenocarcinoma. All other lymph nodes and margins are negative for carcinoma.

Synoptic Data

Clinical History:
Specimen:

Not known: .
Esophagus

[page 3 of 6]
Surgical Pathology Consultation Report

Proximal stomach
Procedure: Esophagogastrectomy
Primary Tumor Site: Esophagogastric junction (EGJ)
Additional Sites Involved by Tumor: Distal esophagus (lower thoracic esophagus)
Proximal stomach and esophagogastric junction
Relationship of Tumor to Esophagogastric Junction:
Tumor midpoint lies in the proximal stomach or cardia and tumor involves the esophagogastric junction
Distance of tumor center from esophagogastric junction: 2.0 cm
Histologic Type: Adenocarcinoma
Histologic Grade: G3: Poorly differentiated
Tumor Size: Greatest dimension: 8.7 cm
Additional dimension: 5.9 cm
Additional dimension: 1.0 cm
Microscopic Tumor Extension: Tumor invades submucosa
Proximal Margin: Uninvolved by invasive carcinoma
Uninvolved by dysplasia
Distal Margin: Uninvolved by invasive carcinoma
Uninvolved by dysplasia
Circumferential (Adventitial) or Deep Margin:
Uninvolved by invasive carcinoma
All Margin Status
All margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.0 mm
Closest margin: Circumferential
Treatment Effect: No prior treatment
Lymph-Vascular Invasion: Present
TNM Descriptors: Not applicable: .
Primary Tumor (pT): pT1b: Tumor invades submucosa
Regional Lymph Nodes (pN): pN1: Regional lymph node metastasis involving 1 to 2 nodes
Number of regional lymph nodes examined: 48
Number of regional lymph nodes involved: 1
Distant Metastasis (pM): Not applicable: .
Additional Pathologic Findings: *Intestinal metaplasia (Barrett's esophagus)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

Esophageal Cancer

Gross Description

1. The specimen labeled with the patient's name and as "ST19 splenic nodes" consists of multiple pieces of fibroadipose tissue measuring, in aggregate, 2.0 x 1.5 x 0.5 cm.
1A submitted in toto
2. The specimen labeled with the patient's name and as "STN 20 celiac nodes" consists of 1 piece of fibroadipose tissue measuring 3.5 x 2.0 x 1.0 cm. Within the tissue is a single lymph node measuring 2.0 x 1.5 x 0.5 cm. Representative sections, lymph node submitted in toto:
2A 1 lymph node, bisected
3. The specimen labeled with the patient's name and as "Common hepatic nodes ST18" consists of multiple pieces of fibroadipose tissue measuring, in aggregate, 1.7 x 2.2 x 0.4 cm.

[page 4 of 6]
3A submitted in toto

4. The specimen labeled with the patient's name and as "Common hepatic nodes ST18" consists of 1 piece of fatty tissue measuring 3.0 x 1.0 x 0.1 cm. The specimen was submitted in toto, at intraoperative consult, as block 4A.

Submitted in toto:

4A frozen section tissue, resubmitted

5. The specimen labeled with the patient's name and as "STN 20 celiac nodes" consists of 1 piece of fibroadipose tissue measuring 1.3 x 0.5 x 0.2 cm.

5A submitted in toto

6. The specimen labeled with the patient's name and as "Lymph node station 4L" consists of 1 anthracotic lymph node measuring 0.7 x 0.4 x 0.3 cm. There are adherent fragments of adipose tissue.

6A submitted in toto

7. The specimen labeled with the patient's name and as "Lymph node STN 7" consists of several ragged piece is of fibroadipose tissue with anthracotic material measuring 2.0 x 1.7 x 0.5 cm.

7A submitted in toto

8. The specimen is labeled with the patient's name and as "Thoracic esophagus + proximal stomach".

RESECTION SPECIMEN: Gastro-esophagectomy received already opened

FIXATION: Received for consultation 10% neutral buffered formalin

DIMENSIONS:

Length along lesser curvature: 8.0 cm

Length along greater curvature: 12.0 cm

Circumference of distal gastric margin: 21.0 cm

Length of tubular esophagus: 10.0 cm

Width of tubular esophagus: 3.8 cm

TUMOR

LOCATION:

- Gastric region: GE junction, circumferential
- 95% of tumor mass located in stomach (cardia)

- **CONFIGURATION:** Circumferential

- **DIMENSIONS:** Diameters: 8.7 x 5.9 cm
Depth: 1.0 cm

- **DESCRIPTIVE CHARACTERISTICS:** Nodular

- **PERFORATION:** No

- **DISTANCE FROM MARGINS:**

- PROXIMAL: 9.5 cm
- DISTAL: 5.0 cm
- RADIAL: 0.5 cm (stomach serosa)

ESTIMATED DEPTH OF INVASION: Just into muscularis mucosa

LESIONS IN NONCANCEROUS STOMACH: None

LESIONS IN NONCANCEROUS ESOPHAGUS: The distal 3 cm of the esophagus is pale comparative to the remainder of the esophagus with slight flattening of the mucosal surface

[page 5 of 6]
LYMPH NODES: Several perigastric lymph nodes along the greater and lesser curvatures

Tissue is stored frozen

Representative Sections:

8A esophagus, proximal to tumor

8B-8L GE junction in toto, starting at the greater curvature and moving in a clockwise direction (tumor where present)

8M-8O distal edge of tumor with adjacent stomach

8P uninvolved stomach

8Q 1 perigastric lymph node, bisected

8R 1 perigastric lymph node, bisected

8S multiple perigastric lymph nodes

8T 1 thoracic esophagus lymph node

ADDITIONAL BLOCKS:

8U-8Z esophagus immediately proximal to GE junction, in toto, starting at the greater curvature and moving in a clockwise direction

8AA-8AD random esophagus, proximal to distal

9. The specimen labeled with the patient's name and as "Proximal esophageal margin" consists of a single piece of elongated tissue with staples at one edge measuring 4.5 x 0.6 x 0.4 cm. At intraoperative consult the soft tissue adjacent to the staple line is submitted as block 9A. Representative section:

9A frozen section tissue, resubmitted

10. The specimen labeled with the patient's name and as "Stomach margin" and consists of a single strip of tissue with a staple line measuring 10.5 cm in length with a width that ranges from 0.9 to 1.3 cm and a thickness of 0.4 cm. There is a possible suture at one end. At intraoperative consult the soft tissue adjacent to the staple line is submitted with block 10A being close to the possible suture and the remainder submitted as block 10B. Representative sections:

10A-10B frozen section tissue, resubmitted

11. The specimen labeled with the patient's name and as "Lymph node STN 7" consists of 1 piece of fibroadipose tissue measuring 4.0 x 2.5 x 1.7 cm. Within the tissue are multiple lymph nodes that measure from 0.1 to 3.5 cm.

Representative sections, lymph nodes submitted in toto:

11A multiple lymph nodes

11B 1 possible lymph node, bisected

12. The specimen labeled with the patient's name and as "Lymph node STN 16" consists of a piece of fibroadipose tissue measuring 5.0 x 3.5 x 1.0 cm. Within the tissue are multiple lymph nodes that measure from 0.3 to 1.3 cm.

Representative sections, lymph nodes submitted in toto:

12A multiple lymph nodes

12B 1 lymph node, bisected

13. The specimen labeled with the patient's name and as "Lymph node STN 17" consists of a piece of fibroadipose tissue measuring 5.5 x 3.5 x 1.5 cm. Within the tissue are multiple lymph nodes that measure from 0.3 to 1.0 cm.

Representative sections, lymph nodes submitted in toto:

13A-13B multiple lymph nodes, per block

13C 1 lymph node, bisected

14. The specimen labeled with the patient's name and as "Lymph node STN 8" consists of multiple pieces of fibroadipose tissue measuring, in aggregate, 4.5 x 4.5 x 2.0 cm. Within the tissue are multiple lymph nodes that measure from 0.2 to 1.2 cm. Representative sections, lymph node submitted in toto:

14A 248 lymph nodes

14B 2 lymph nodes

14C 1 lymph node, bisected

15. The specimen labeled with the patient's name and as "Final esophageal margin" consists of a piece of mucosa, stapled at one end, measuring 3.5 x 0.5 x 0.5 cm. No obvious lesions are identified. Representative sections:

15A tissue adjacent to staple line

[page 6 of 6]
16. The specimen labeled with the patient's name and as "Final gastric resection margin" consists of a wedge-shaped piece of mucosa, with multiple staple lines, measuring 6.5 x 2.0 x 1.0 cm. No gross lesions are identified.

Representative sections:

16A-16B tissue adjacent to staple lines

17. The specimen labeled with the patient's name and as "Donuts" consists of 2 rings of mucosa measuring 1.2 and 3.2 cm in diameter. The large piece demonstrates blue suture material. Submitted in toto:

17A smaller piece, bisected

17B larger piece

Quick Section Diagnosis

4. Common Hepatic Nodes ST18: QS4A: Lymph node, negative for carcinoma.
Case reported to OR at

9. Proximal esophagus margin: QS9A: No evidence of malignancy

10. Stomach margin: QS10A and 10B: No evidence of malignancy.

Case reported to OR at

Revised due to PHI.

Criteria:	hw 5/20/14	Yes	No

Source: NCI Genomic Data Commons file ee03791e-aba1-4257-aee6-bf7e0bcfba15 (TCGA-JY-A939.C5B0F2A9-9BE4-4FF4-AC75-62C4ED14E5F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).